Somatic mutation profile of tumor specimen TCGA-J8-A3YD-01A (aliquot TCGA-J8-A3YD-01A-11D-A22Z-08) from TCGA case TCGA-J8-A3YD, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 47.7 years (17,416 days).
Specimen TCGA-J8-A3YD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48a24c72-e400-4d3c-9d50-679acf5e876d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J8-A3YD-10A (Blood Derived Normal), aliquot TCGA-J8-A3YD-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e0efe09f-a5c2-4f2b-884f-5d11c8b383ab

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 4, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- GDI1 | c.924C>G p.I308M | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50130746; called by muse, varscan2
- JPH2 | c.1230G>C p.Q410H | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100881650; called by muse, mutect2
- NOTCH4 | c.3508T>C p.C1170R | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100900474; called by muse, mutect2, varscan2
- TF | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV53924986; called by muse, mutect2
- DIAPH1 | c.1673C>T p.A558V | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.292); called by muse, mutect2
- TMEM67 | c.2201C>A p.A734E | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- C6orf15 | c.876C>A p.I292= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV99456714; called by muse, mutect2, varscan2
- DCTN1 | c.2355G>A p.R785= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV100720887; called by muse, mutect2, varscan2
- PML | c.441C>T p.L147= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV99166756; called by muse, mutect2, varscan2
- ZSCAN4 | c.306C>T p.A102= | Silent (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- UVSSA | c.*8672G>C | 3'UTR (SNP) | VAF 28/322 reads (9%) | catalogued as COSV100245916; called by muse, mutect2
